Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A6EK, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A6EK-01A (Primary Tumor).

ICD-O-3

*Carcinoma, squamous cell
keratinizing NOS 8071/3
Site Larynx NOS 032.9
W 5/24/13*

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge: **Surgery and Laryngological Oncology Dept.**

Physician in charge:

Clinical diagnosis (suspicion) **Laryngeal carcinoma (Hist.pat.: Ca planoepitheliale verrucosae)**

Date of admission: (urgency: intraoperative)

Material:

1) Material: tumour of the larynx. Please examine the marked margins. Method of collection: Collection of specimens for laboratory examination

Histopathological Diagnosis

Examination performed on:

**Invasive squamous carcinoma of the larynx, keratinizing
Carcinoma planoepitheliale keratodes invasivum (verrucosum) laryngis.
G1, pT2, pN0 (Delphian).**

*** codes according to ICD-O-3 or SNOMED**

Macroscopic description:

Surgical specimen sized 9 x 5.5 x 5cm, including larynx with the hyoid bone. Tumour sized 2.6 x 2.6 x 1.0 cm in the glottis region, right side, infiltrating the subglottal and supraglottal regions.

Microscopic description:

Carcinoma planoepitheliale keratodes invasivum (verrucosum)G1 glottis.

The tumour invading the subglottal and supraglottal regions.

Surgical incision lines off cancer invaded area.

No signs of vascular and nerve invasion found. Sinus histiocytosis lymphonodorum No I (Delphian)

Assistant:

Pathologist:

Edited by

Results of intraoperative examination:

Examination performed on:

Neoplastic lesions not found.

Final reply to be given after the analysis of paraffin specimens.

Assistant:

Pathologist

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 4bba7d5f-8e25-4bee-8922-7e5fb8c6bef2 (TCGA-D6-A6EK.9D693044-26F6-4406-8735-8854BF18358C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).